Somatic mutation profile of tumor specimen TCGA-ZA-A8F6-01A (aliquot TCGA-ZA-A8F6-01A-23D-A364-08) from TCGA case TCGA-ZA-A8F6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 71.5 years (26,122 days).
Specimen TCGA-ZA-A8F6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73e822f9-11bd-4b70-87cc-35e2ed5c6e80.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZA-A8F6-10A (Blood Derived Normal), aliquot TCGA-ZA-A8F6-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff6dc1d0-9cd1-41a2-93ee-7285001befed

The open-access MAF lists 48 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Nonsense Mutation 7, Silent 7, Frame Shift Del 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RHOA | c.169T>G p.L57V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV69041945; called by muse, mutect2, varscan2
- AMY2B | c.1337A>G p.N446S | Missense Mutation (SNP) | VAF 71/409 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as rs753373702, COSV100796256; called by muse, mutect2, varscan2
- ANKRD35 | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.249); catalogued as rs377047896; called by muse, mutect2, varscan2
- ARMCX2 | c.1391G>A p.R464Q | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT tolerated (0.22); PolyPhen benign (0.231); catalogued as rs1556051740, COSV100168045, COSV57529622; called by muse, mutect2, varscan2
- CARS1 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV99542457; called by muse, mutect2, varscan2
- CD163L1 | c.3436G>T p.E1146* | Nonsense Mutation (SNP) | VAF 28/174 reads (16%) | catalogued as COSV100549926, COSV58016152; called by muse, mutect2, varscan2
- CNTNAP4 | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100270531; called by muse, mutect2, varscan2
- DNAH9 | c.12446G>C p.G4149A | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs757478102, COSV99305192; called by muse, mutect2, varscan2
- DSCAML1 | c.4961C>T p.T1654I (on ENST00000321322; = p.T1594I on NM_020693.4) | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as COSV100355518, COSV58400979; called by muse, mutect2, varscan2
- DYRK2 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.333); catalogued as COSV100165249; called by muse, mutect2, varscan2
- ERI1 | c.790T>C p.Y264H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99141306; called by muse, mutect2, varscan2
- F13B | c.275C>G p.T92S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV100803252; called by muse, mutect2, varscan2
- FLII | c.1208C>T p.A403V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as rs775990658, COSV100493571; called by muse, mutect2, varscan2
- GAB4 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV68752870; called by muse, mutect2, varscan2
- GFPT2 | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs1010915951, COSV53807947; called by muse, mutect2, varscan2
- GRIN2A | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751692867, COSV58046793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HERC5 | c.2057G>T p.R686I | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV99987593; called by muse, mutect2, varscan2
- HGF | c.701G>C p.R234P | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55948651, COSV99736410; called by muse, mutect2, varscan2
- INTS7 | c.421C>T p.H141Y | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV100877457; called by muse, mutect2, varscan2
- ITGAV | c.1615C>T p.R539* | Nonsense Mutation (SNP) | VAF 37/123 reads (30%) | catalogued as COSV53709466; called by muse, mutect2, varscan2
- MATN1 | c.790+2T>C p.X264_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV101056246; called by muse, mutect2, varscan2
- MED15 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99487575; called by muse, mutect2, varscan2
- MEX3B | c.1071del p.E358Sfs*169 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | catalogued as COSV61662929; called by mutect2, pindel, varscan2
- NCAPG2 | c.2362C>T p.L788F | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99316777; called by muse, mutect2, varscan2
- NKAPL | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100642486; called by mutect2, varscan2
- OR52K1 | c.871C>G p.P291A | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100297611, COSV56902990; called by muse, mutect2, varscan2
- OR8A1 | c.311T>G p.F104C | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99420480; called by muse, mutect2, varscan2
- PCDHB14 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 17/120 reads (14%) | catalogued as COSV99505743; called by muse, mutect2, varscan2
- PTGER3 | c.640C>T p.R214* | Nonsense Mutation (SNP) | VAF 14/122 reads (11%) | catalogued as COSV100138462; called by muse, mutect2, varscan2
- QKI | c.255A>C p.K85N | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99274770; called by muse, mutect2, varscan2
- RETREG2 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 46/268 reads (17%) | SIFT tolerated (1); PolyPhen possibly damaging (0.696); catalogued as COSV99811483; called by muse, mutect2, varscan2
- SIPA1L3 | c.1517A>T p.D506V | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as COSV99728166; called by muse, mutect2, varscan2
- TAS1R2 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as rs79635934, COSV64743865; called by muse, mutect2, varscan2
- TEX37 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.911); catalogued as rs577813909; called by muse, mutect2, varscan2
- TMEM154 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV100433059; called by muse, mutect2, varscan2
- TP53TG5 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140964438, COSV65577525; called by muse, mutect2, varscan2
- UAP1L1 | c.526C>A p.P176T | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as COSV100814429; called by muse, mutect2
- VPS13C | c.7420C>T p.Q2474* (on ENST00000644861 / NM_020821.3; = p.Q2431* on NM_017684.5) | Nonsense Mutation (SNP) | VAF 23/118 reads (19%) | catalogued as COSV99827993; called by muse, mutect2, varscan2
- ZC3H14 | c.1639G>A p.V547I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs746385996, COSV99193003; called by muse, mutect2, varscan2
- SV2C | c.1457del p.T486Kfs*18 | Frame Shift Del (DEL) | VAF 16/95 reads (17%) | called by mutect2, pindel, varscan2
- LIMCH1 | c.606C>T p.F202= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs138213439; called by muse, mutect2, varscan2
- MLLT11 | c.54C>A p.P18= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV100927388; called by muse, mutect2, varscan2
- RABGAP1 | c.501C>G p.A167= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as rs374096472; called by muse, mutect2, varscan2
- RNF14 | c.765C>T p.I255= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as COSV100641194; called by muse, mutect2, varscan2
- SLC26A7 | c.1812A>G p.V604= | Silent (SNP) | VAF 22/140 reads (16%) | catalogued as COSV99403066; called by muse, mutect2, varscan2
- TM7SF3 | c.840G>A p.E280= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs149730466; called by muse, mutect2, varscan2
- TP53 | c.555C>T p.S185= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as rs367560109, COSV52661660, COSV52701195, COSV52772909; ClinVar: likely benign; called by muse, mutect2, varscan2
- Y_RNA | chr7:75516149 C>G | 5'Flank (SNP) | VAF 15/129 reads (12%) | called by muse, mutect2, varscan2
